Somatic mutation profile of tumor specimen TARGET-10-PATKGP-09A (aliquot TARGET-10-PATKGP-09A-01D) from TARGET case TARGET-10-PATKGP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.6 years (3,861 days).
Specimen TARGET-10-PATKGP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82ff9066-1c21-41b0-bef1-0f24ce7a4ab5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATKGP-10A (Blood Derived Normal), aliquot TARGET-10-PATKGP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26fadfc9-2d73-4ee4-879a-de4755601c88

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY9 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53576434; called by muse, mutect2, varscan2
- CRYGD | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV52206015; called by muse, mutect2, varscan2
- DNM2 | c.1976T>A p.L659Q (on ENST00000355667 / NM_001005360.3; = p.L655Q on NM_004945.3) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58970976; called by muse, varscan2
- ELP5 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen probably damaging (0.941); catalogued as COSV63040157; called by muse, mutect2, varscan2
- EPGN | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59740970; called by muse, mutect2, varscan2
- FAM222A | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV62723964; called by muse, mutect2, varscan2
- FBXW7 | c.1439A>C p.D480A (on ENST00000281708 / NM_001349798.2; = p.D400A on NM_018315.5) | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55916929, COSV55952469; called by muse, varscan2
- MCC | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs199564726; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- OOEP | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64859125; called by muse, mutect2, varscan2
- OR1F1 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV58962281; called by muse, mutect2, varscan2
- PMM1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53448289, COSV53449316; called by muse, mutect2, varscan2
- OR5BS1P | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERN1 | c.1563G>A p.S521= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs758467855, COSV101458374; called by muse, mutect2, varscan2
- JAKMIP3 | c.1623C>T p.A541= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as rs771434869; called by muse, mutect2, varscan2
- KCNA2 | c.1053C>T p.A351= | Silent (SNP) | VAF 53/146 reads (36%) | catalogued as rs748008112; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO18B | c.4137C>T p.V1379= | Silent (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- AL138999.2 | chr13:33350428 C>G | 3'Flank (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-938T>C | Intron (SNP) | VAF 11/376 reads (3%) | called by muse, mutect2
